Surgical pathology report (de-identified scan), TCGA case TCGA-66-2742, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2742-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right lung and others

Clinical diagnosis and question

Squamous cell carcinoma of right upper lobe, malignancy?

REPORT ON FINDINGS**Macroscopy**

- 1.) LN right middle lobe: 1.5 cm lesioned node, section surfaces speckled black in places, grayish-white patches in places and indurated.
- 2.) LN right upper lobe: 1.5 cm lesioned node, section surfaces with section surfaces as described under 1.).
- 3.) Right lung: inflated, fixed lung measuring 19 x 15 cm at the base and up to 24 cm in length, central bronchus resection line located 0.5 cm proximal to the point where the upper lobe bronchus arises. S1 with deep notch in the sagittal plane extending close to the hilus. Upper pleural fissure largely obliterated, only recognizable in a short segment of the dorsal region. Pleura with intensive, partly diffuse and partly reticular or patchy black pigmentation. Pleura above Segments 1 + 3 shows diffuse grayish-white discoloration especially in the lateral region. At the point where the upper lobe bronchus arises and its first branch is located a moderately solid tumor, max. 8.5 cm in size, with the primary mass in the upper lobe, of unclear and somewhat arcuate demarcation, predominantly pale brownish and in sections pathc grayish-black pigmentation, with excentric cavity of irregular configuration and max. 2.6 cm in size. Initial extension of tumor to the middle lobe at the pleural fissure. Tumor extension to the star-shaped area of shrinkage there in the ventrolateral visceral pleura above Segment 3 and and as far as the pleura above Segment 1 in the region of the whitish discoloration. Distance from hilar resection surface at least 0.3 cm. Marked narrowing of central and intermediate sections of the upper lobe bronchi and also truncation of peripheral branches of B1-3 in the tumor. Involvement of some black pigmented nodes up to 1.5 cm in size by the tumor, one of these located at the hilus. In the middle lobe, 0.7 cm pale brown-whitish tumor of unclear demarcation at least 0.8 cm from tumor margin in the proximity of the pleural fissure. Parenchyma in the tumor environment partly indurated and brownish-yellow in patches, peripheral bronchi of the upper lobe dilated and filled with thick mucus. In the lower lobe, especially in the dorsal segment, numerous hard areas measuring up to 0.2 cm partly in the subpleural region and partly in the parenchyma. In the subpleural region of Segment 7, a whitish strip-like area 0.3 cm in size. Remaining parenchyma, especially in the subpleural and basal region in the lower lobe, diffusely indurated with suggestion of grayish-white reticular pattern, lung surface in these sections partly suggestive of pavement relief. At the hilus three grayish-black node lesions between 0.7 and 1.1 cm in size.
- 4.) Right parietal pleura: Flat or membranous area measuring 14 x max. 4.5 cm and up to 0.2 cm thick. Surface predominantly smooth, fatty tissue on the other side.
- 5.) Hilar LN (Item 10) right: 1.8 cm lesioned grayish-black node with some surrounding tissue.
- 6.) Subcarinal LN (Item 7): 2.5 cm lesioned grayish-black node with some surrounding tissue.
- 7.) Deep paratracheal LN (Item 4) right: two lesioned grayish-black nodes, 0.5 and 1.3 cm in size.
- 8.) Hilar LN (Item 10) left: 1.5 cm lesioned grayish-black node.

Examined:

- 1.) + 2.) Rapid section remains + residual material,
- 3.) Tumor with remaining parenchyma, including involved nodes + proximal section of B2, 2 sections with lateral pleura above S3, 2 sections with pleura above S1, hilar resection surface (color marking), main bronchus, upper pleural fissure (color marking), secondary tumor in middle lobe, 5 sections of hard areas in S10+9, strip-like white-speckled zone in Segment 7 (halved), S9 basal, S10 dorsal, central bronchus resection line + resection margins vessels, hilar nodes,
- 4.) 5 sections,
- 5.) nodes (halved),
- 6.) - 8.) All material (in 6. nodes, in 7. large nodes halved in each case),
- 24 blocks, partly [REDACTED], PAS, and diastase-PAS, iron.

[page 2 of 2]
Microscopy

1.) + 2.) Immediate intraoperative evaluation (■■■■■): LN with anthracotic pigment deposit and sclerosis zones, no evidence of tumor in the samples.

Description of histological and cytological findings omitted for capacity reasons.

EVALUATION

Primary diagnosis/diagnoses

Extensive, large cell, non-keratinizing, bronchopulmonary squamous cell carcinoma of the upper lobe of the right lung with poor histological differentiation, extending from central to peripheral regions, with partially extensive necrotic changes. Tumor classification based on the existing picture pT2 pN1 pM1 V1 R0, stage IV. C34.1 M8070/3. G3.

Secondary diagnosis/diagnoses

Overall still slight discontinuous interstitial fibrosis of the lung parenchyma in the mantle zone with perifocal emphysema. Subpleural fibrous remodeled area of lung parenchyma in S7. Moderately marked mixed pigmented storage of dust in the lung tissue and in places high-grade (*appears to be a word missing here*) of lymph nodes with inclusion of very small anisotropic particles. Marked cluster of alveolar siderophages in places. Peritumoral accentuated slight active and partly resorptive pneumonia. Small foci of mature metaplastic ossification of lung tissue. Diffuse and nodular zones of sclerosis in lymph nodes. Slight, focally accentuated chronic parietal pleuritis with short sections of reactive mesothelial proliferation and likewise short sections of slight fibrosis (sample 4.)).

Remark/addendum

The carcinoma has grown centrally as far as the main bronchus and in peripheral regions shows areas of slight invasion of the hypocellular fibrosed visceral pleura. It is therefore not possible to decide whether the carcinoma has arisen in the periphery of the lung or in the center of the bronchial pathway. The lymph node metastases, like the isolated invasions of small vessels, lie within the tumor or the bronchopulmonary region. Apart from the main tumor, which has penetrated focally across the transverse pleural fissure into the adjacent section of middle lobe, a separate small tumor focus has been detected in the middle lobe. This is classified as a satellite nodule in another lobe, although histologically it hardly shows a squamous epithelial differentiation and contains a small light-cell solid component. A tumor-associated high-grade inflammation is also found here. The etiology of the interstitial pulmonary fibrosis, which shows only minimal process activity, is histologically unclear: there may be an association with respiratory bronchiolitis.

Source: NCI Genomic Data Commons file c50d461f-2408-4941-ba65-961d33be9850 (TCGA-66-2742.07C5C025-C1CD-486E-B510-EBC19D3E53D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).